Somatic mutation profile of tumor specimen TCGA-Q9-A6FU-01A (aliquot TCGA-Q9-A6FU-01A-11D-A31U-09) from TCGA case TCGA-Q9-A6FU, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 57.8 years (21,108 days).
Specimen TCGA-Q9-A6FU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 45003556-7588-4a6a-8bda-b4112b39f3a0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-Q9-A6FU-10A (Blood Derived Normal), aliquot TCGA-Q9-A6FU-10A-01D-A31U-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9b03f1d6-94ab-4729-9dd9-3994b71e813c

The open-access MAF lists 162 somatic variants for this specimen: 124 protein-altering or splice-affecting, 34 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 107, Silent 34, Nonsense Mutation 8, Splice Site 3, Splice Region 3, Frame Shift Del 2, Intron 2, 3'UTR 1, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADSL | c.926G>A p.R309H | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749817666; ClinVar: uncertain significance; called by muse, varscan2
- C22orf31 | c.453G>C p.E151D | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.75); catalogued as COSV99326555; called by muse, mutect2, varscan2
- C5orf34 | c.1556T>C p.I519T | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as rs145050535, COSV60928863; called by muse, mutect2, varscan2
- CCT8L2 | c.926A>C p.K309T | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as rs1221765417, COSV63461632; called by muse, mutect2, varscan2
- CLEC4C | c.566A>G p.E189G | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs1565458211; called by muse, mutect2, varscan2
- CSMD2 | c.3907G>A p.E1303K | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as rs756045595, COSV99592111; called by muse, mutect2, varscan2
- CYB5R3 | c.156C>T p.I52= | Splice Region (SNP) | VAF 19/78 reads (24%) | catalogued as COSV61545899; called by muse, mutect2, varscan2
- EIF3J | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as COSV99970679; called by muse, mutect2, varscan2
- F10 | c.1037G>A p.R346H | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.622); catalogued as rs781413602, COSV65021184; called by muse, mutect2, varscan2
- FAM219B | c.272C>T p.S91L | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV62946690; called by muse, mutect2, varscan2
- FGF13 | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs768293112, COSV100264529; called by muse, mutect2, varscan2
- GABRA6 | c.769C>A p.L257I | Missense Mutation (SNP) | VAF 26/40 reads (65%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV50892518; called by muse, mutect2, varscan2
- HUWE1 | c.10141A>G p.S3381G | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as COSV53335094; called by muse, mutect2, varscan2
- IFIT3 | c.914A>G p.E305G | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV99259703; called by muse, mutect2, varscan2
- IGHV3-16 | c.94C>G p.Q32E | Missense Mutation (SNP) | VAF 43/136 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.227); catalogued as rs58425668; called by muse, mutect2, varscan2
- IGKV2-28 | c.61G>A p.D21N | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.331); catalogued as rs547009276; called by muse, mutect2, varscan2
- IL1R1 | c.289G>A p.V97M | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.697); catalogued as rs1488308636, COSV52106335; called by muse, mutect2, varscan2
- KIAA2013 | c.1810del p.L604Sfs*33 | Frame Shift Del (DEL) | VAF 10/26 reads (38%) | catalogued as COSV64860573; called by mutect2, pindel, varscan2
- KIF13B | c.2515C>T p.R839* | Nonsense Mutation (SNP) | VAF 6/15 reads (40%) | catalogued as rs1279400074, COSV72879497; called by muse, mutect2, varscan2
- LDB2 | c.100G>C p.E34Q | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV58775490, COSV58783722; called by muse, mutect2, varscan2
- LRRTM2 | c.1537G>C p.E513Q | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51220445; called by muse, mutect2, varscan2
- MAGEC3 | c.1634A>T p.K545M | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as COSV68923830; called by muse, mutect2, varscan2
- MAGI3 | c.182C>G p.S61W | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1033304573; called by muse, mutect2, varscan2
- MAML3 | c.1297C>T p.R433W | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750620797, COSV59077342; called by muse, mutect2, varscan2
- MED13 | c.3718C>T p.R1240C | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs202062658, COSV67267345; called by muse, mutect2, varscan2
- MROH2B | c.3325G>C p.E1109Q | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.037); catalogued as COSV101270924, COSV68181885, COSV68186148; called by muse, mutect2, varscan2
- NOTUM | c.688G>A p.G230R | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1348442140, COSV99072610; called by muse, mutect2, varscan2
- NOX1 | c.965G>A p.G322E | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372154041; called by muse, mutect2, varscan2
- PCDHA7 | c.1556C>T p.A519V | Missense Mutation (SNP) | VAF 49/89 reads (55%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.651); catalogued as rs1352596879; called by muse, mutect2, varscan2
- PEX2 | c.884C>G p.S295* | Nonsense Mutation (SNP) | VAF 9/38 reads (24%) | catalogued as rs1554584377; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RIPK4 | c.1064dup p.E356Gfs*21 (on ENST00000352483; = p.E308Gfs*21 on NM_020639.3) | Frame Shift Ins (INS) | VAF 10/35 reads (29%) | catalogued as rs746595711; called by mutect2, pindel, varscan2
- RTCB | c.245C>G p.S82C | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs756011780; called by muse, mutect2, varscan2
- RUNDC3A | c.597C>G p.I199M | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as COSV56586438; called by muse, mutect2, varscan2
- SCUBE1 | c.1607G>A p.R536H | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs778296868, COSV62610966; called by muse, mutect2, varscan2
- SEMA6D | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV60379586; called by muse, mutect2, varscan2
- SLC38A3 | c.876C>G p.I292M | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1172421372; called by muse, mutect2, varscan2
- SLC45A1 | c.1548C>G p.I516M | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.997); catalogued as rs1419919692; called by muse, mutect2
- SMAD4 | c.1586T>G p.L529* | Nonsense Mutation (SNP) | VAF 15/37 reads (41%) | catalogued as COSV61688407, COSV61689110; called by muse, mutect2, varscan2
- SRRM2 | c.4065G>C p.L1355F | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.467); catalogued as COSV57082234; called by muse, mutect2, varscan2
- TEX9 | c.1099-1G>C p.X367_splice | Splice Site (SNP) | VAF 8/30 reads (27%) | catalogued as rs1201869303; called by muse, varscan2
- TMBIM4 | c.249G>C p.L83F | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.042); catalogued as rs1454911794; called by muse, mutect2, varscan2
- VN1R2 | c.40C>G p.P14A | Missense Mutation (SNP) | VAF 8/25 reads (32%) | PolyPhen possibly damaging (0.539); catalogued as rs189749880; called by muse, mutect2, varscan2
- XPO4 | c.503C>G p.S168* | Nonsense Mutation (SNP) | VAF 4/19 reads (21%) | catalogued as COSV55007629; called by muse, mutect2, varscan2
- ZBED8 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.07); catalogued as COSV68824895; called by muse, mutect2, varscan2
- ZFP57 | c.892C>T p.P298S | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.057); catalogued as COSV65307213; called by muse, mutect2, varscan2
- ZNF195 | c.1772C>G p.S591* (on ENST00000399602 / NM_001130520.3; = p.S519* on NM_007152.5) | Nonsense Mutation (SNP) | VAF 16/48 reads (33%) | catalogued as COSV50008885; called by muse, mutect2, varscan2
- ZNF280A | c.590C>G p.P197R | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.075); catalogued as COSV57482205; called by muse, mutect2
- ZNF721 | c.22G>A p.D8N (on ENST00000338977; = p.D20N on NM_133474.4) | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.044); catalogued as rs1481105815, COSV100167817; called by muse, mutect2, varscan2
- ACTR5 | c.964G>C p.E322Q | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.953); called by muse, mutect2
- ADAM12 | c.2611C>G p.H871D | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.61); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADAMTS3 | c.1502C>A p.P501Q | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- AFF3 | c.2531G>C p.R844T | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- AFM | c.925G>C p.E309Q | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- AKAP9 | c.4850A>T p.E1617V | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANO5 | c.1552G>A p.G518R | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- ANXA4 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARL2BP | c.94A>C p.I32L | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- ARMC4 | c.2362G>A p.E788K | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.62); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- BIRC6 | c.5899G>C p.D1967H | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- C9orf24 | c.454G>C p.E152Q | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- CCDC22 | c.1105T>A p.C369S | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CD163 | c.2736G>C p.K912N | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- CEP162 | c.415G>C p.E139Q | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.357); called by muse, mutect2, varscan2
- CFH | c.1504C>T p.Q502* | Nonsense Mutation (SNP) | VAF 13/42 reads (31%) | called by muse, mutect2, varscan2
- CNOT1 | c.3940G>C p.E1314Q | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CNTRL | c.1836G>C p.K612N | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- CTAGE6 | c.781G>A p.D261N | Missense Mutation (SNP) | VAF 25/233 reads (11%) | SIFT tolerated (0.81); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- CTNNA2 | c.714_715delinsT p.N239Tfs*54 | Frame Shift Del (DEL) | VAF 3/26 reads (12%) | called by muse*, pindel
- DGKK | c.1915C>G p.P639A | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- DPP6 | c.2486C>G p.S829C (on ENST00000377770 / NM_001364500.2; = p.S767C on NM_001936.5) | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- ELP1 | c.2482G>C p.E828Q | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- ELP1 | c.1396G>C p.G466R | Missense Mutation (SNP) | VAF 27/39 reads (69%) | SIFT deleterious (0.02); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- FAM120C | c.2217G>A p.M739I | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- FBXL16 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- FBXL4 | c.1159T>A p.F387I | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- FBXO3 | c.942G>A p.M314I | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- GSDMC | c.682C>G p.L228V | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- IGHV3-43 | c.40T>G p.L14V | Missense Mutation (SNP) | VAF 54/89 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- INPP4B | c.733G>A p.D245N | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- KLF8 | c.725C>T p.S242L | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- LILRA4 | c.954A>C p.G318= | Splice Region (SNP) | VAF 19/66 reads (29%) | called by muse, mutect2, varscan2
- LRRC34 | c.181T>C p.C61R | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAP3K15 | c.2931C>G p.L977= | Splice Region (SNP) | VAF 32/80 reads (40%) | called by muse, mutect2, varscan2
- MAP3K15 | c.1904A>T p.E635V | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- MORC2 | c.2288G>C p.R763T (on ENST00000397641 / NM_001303256.3; = p.R701T on NM_014941.3) | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MRPL1 | c.724G>C p.E242Q | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.625); called by muse, mutect2
- MYLK3 | c.59C>T p.T20I | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MYO7B | c.378T>G p.H126Q | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- NID2 | c.2036C>G p.S679C | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- NLRC4 | c.436C>A p.H146N | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.96); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NUTM2F | c.1855C>G p.P619A | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.228); called by mutect2, varscan2
- OR2L13 | c.196T>C p.S66P | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OR51Q1 | c.369C>A p.D123E | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR5B2 | c.683C>T p.S228L | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- OR9Q1 | c.326C>G p.S109C | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); called by muse, mutect2
- PF4V1 | c.17G>C p.R6T | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PGRMC2 | c.518C>G p.S173* | Nonsense Mutation (SNP) | VAF 5/18 reads (28%) | called by muse, mutect2, varscan2
- PHIP | c.3689A>G p.Y1230C | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PJVK | c.668-1G>A p.X223_splice | Splice Site (SNP) | VAF 15/46 reads (33%) | called by muse, mutect2, varscan2
- PKD1L1 | c.2275C>G p.Q759E | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- PKHD1L1 | c.959G>C p.S320T | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.62); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RCL1 | c.106C>T p.R36W | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- RET | c.829G>C p.D277H | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- RFX7 | c.580C>G p.Q194E (on ENST00000559447 / NM_001368074.1; = p.Q291E on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.251); called by muse, mutect2
- RIMS2 | c.1202G>C p.R401T (on ENST00000666250 / NM_001348490.2; = p.R209T on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.183); called by muse, mutect2
- RNF115 | c.429-1G>A p.X143_splice | Splice Site (SNP) | VAF 17/59 reads (29%) | called by muse, mutect2, varscan2
- SCAF1 | c.3448C>G p.P1150A | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.31); called by muse, mutect2
- SLC1A5 | c.1516C>T p.P506S | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SOS1 | c.2437G>C p.D813H | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPATA31A1 | c.788C>G p.S263C | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- SPEN | c.10336T>C p.S3446P | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- SPRTN | c.1378C>G p.Q460E | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- STK35 | c.1090G>C p.D364H | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- STT3B | c.2469G>C p.K823N | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- SUCNR1 | c.154C>G p.L52V | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- SYNE2 | c.7821G>T p.W2607C | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- TACO1 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- TANGO6 | c.196C>G p.Q66E | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM11 | c.196C>G p.R66G | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- TTN | c.98754C>G p.I32918M (on ENST00000591111; = p.I25494M on NM_003319.4) | Missense Mutation (SNP) | VAF 9/30 reads (30%) | PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- UBA1 | c.3037C>G p.Q1013E | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- UROD | c.512C>G p.S171* | Nonsense Mutation (SNP) | VAF 7/25 reads (28%) | called by muse, mutect2, varscan2
- VWA8 | c.1355G>T p.G452V | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- XYLT1 | c.592G>C p.E198Q | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); called by muse, mutect2
- APAF1 | c.1626G>A p.E542= (on ENST00000551964 / NM_181861.2; = p.E531= on NM_001160.3) | Silent (SNP) | VAF 11/70 reads (16%) | called by muse, mutect2, varscan2
- C1QL3 | c.435C>T p.F145= | Silent (SNP) | VAF 8/36 reads (22%) | called by muse, mutect2, varscan2
- CCDC146 | c.1365A>T p.V455= | Silent (SNP) | VAF 14/29 reads (48%) | called by muse, mutect2, varscan2
- CEACAM6 | c.837A>G p.Q279= | Silent (SNP) | VAF 34/123 reads (28%) | called by muse, mutect2, varscan2
- DDX51 | c.1044C>T p.G348= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as rs920372873; called by muse, mutect2
- DUSP6 | c.201G>A p.Q67= | Silent (SNP) | VAF 6/18 reads (33%) | called by muse, mutect2
- EPS8 | c.1071G>A p.L357= | Silent (SNP) | VAF 10/36 reads (28%) | called by muse, mutect2, varscan2
- FLNA | c.6345C>T p.I2115= (on ENST00000369850 / NM_001110556.2; = p.I2107= on NM_001456.3) | Silent (SNP) | VAF 16/35 reads (46%) | called by muse, mutect2, varscan2
- KDM5C | c.612C>T p.S204= | Silent (SNP) | VAF 11/56 reads (20%) | called by muse, mutect2, varscan2
- KIF5B | c.1743C>T p.G581= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as rs1430381017; called by muse, mutect2, varscan2
- KIZ | c.15C>T p.L5= | Silent (SNP) | VAF 6/20 reads (30%) | called by muse, mutect2, varscan2
- MARCHF4 | c.831C>T p.Y277= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs138565372, COSV56104900; called by muse, mutect2, varscan2
- MCM2 | c.933G>A p.V311= | Silent (SNP) | VAF 14/54 reads (26%) | called by muse, mutect2, varscan2
- OOEP | c.60C>T p.S20= | Silent (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- OR4A15 | c.198C>T p.F66= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as rs747544149, COSV59035389, COSV59036344; called by muse, mutect2, varscan2
- OR4D6 | c.351G>A p.V117= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV100271830; called by muse, mutect2
- OR5V1 | c.504C>T p.F168= | Silent (SNP) | VAF 28/36 reads (78%) | called by muse, mutect2, varscan2
- P2RY12 | c.633C>G p.L211= | Silent (SNP) | VAF 52/113 reads (46%) | called by muse, mutect2, varscan2
- PFKFB2 | c.1215G>A p.K405= | Silent (SNP) | VAF 7/41 reads (17%) | called by muse, mutect2, varscan2
- PKHD1 | c.12180C>T p.F4060= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV100944625, COSV64380574; called by muse, mutect2, varscan2
- PLCXD3 | c.12T>A p.S4= | Silent (SNP) | VAF 11/41 reads (27%) | called by muse, mutect2, varscan2
- PLS1 | c.33G>A p.E11= | Silent (SNP) | VAF 12/92 reads (13%) | called by muse, mutect2, varscan2
- PLXNA3 | c.4806C>T p.L1602= | Silent (SNP) | VAF 9/18 reads (50%) | called by mutect2, varscan2
- PTAR1 | c.48G>C p.V16= | Silent (SNP) | VAF 26/90 reads (29%) | catalogued as rs1380483746; called by muse, mutect2, varscan2
- PXMP2 | c.366C>T p.L122= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV58095239; called by muse, mutect2, varscan2
- RPE65 | c.18G>A p.E6= | Silent (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- SH2D5 | c.777G>A p.L259= (on ENST00000444387 / NM_001103161.2; = p.L175= on NM_001103160.2) | Silent (SNP) | VAF 7/26 reads (27%) | called by muse, mutect2, varscan2
- SPEF1 | c.642C>G p.L214= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as rs749206059; called by muse, mutect2, varscan2
- SYNJ2 | c.1986G>A p.A662= | Silent (SNP) | VAF 11/21 reads (52%) | catalogued as rs374135325; called by muse, varscan2
- TRIM52 | c.213G>A p.A71= | Silent (SNP) | VAF 9/18 reads (50%) | called by muse, mutect2
- TRIM6-TRIM34 | c.1629G>A p.Q543= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV61454337, COSV61455659; called by muse, mutect2, varscan2
- TRPV6 | c.843C>T p.L281= | Silent (SNP) | VAF 29/106 reads (27%) | catalogued as COSV100844188, COSV63891889; called by muse, mutect2, varscan2
- UNC50 | c.426G>A p.V142= | Silent (SNP) | VAF 6/139 reads (4%) | called by muse, mutect2
- ZBTB39 | c.75C>G p.L25= | Silent (SNP) | VAF 22/91 reads (24%) | called by muse, mutect2, varscan2
- DCX | c.-22-453G>A | Intron (SNP) | VAF 18/69 reads (26%) | called by muse, mutect2, varscan2
- RFX7 | c.-69G>C | 5'UTR (SNP) | VAF 7/37 reads (19%) | called by muse, mutect2, varscan2
- SEPTIN9 | c.722-6399G>A | Intron (SNP) | VAF 10/17 reads (59%) | catalogued as rs781371974, COSV61211231; called by muse, mutect2, varscan2
- VNN3 | c.*312G>A | 3'UTR (SNP) | VAF 15/48 reads (31%) | catalogued as rs1562227557; called by muse, mutect2, varscan2
